Somatic mutation profile of tumor specimen HCM-CSHL-0088-C25-01A (aliquot HCM-CSHL-0088-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0088-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.4 years (27,551 days).
Specimen HCM-CSHL-0088-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89f49eae-f524-4683-b4a0-4f0851d539f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0088-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0088-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3427643b-9b44-4692-8f4d-7316b332c324

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 3, 5'UTR 3, Splice Site 2, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/248 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SLC22A5 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386134223, CM033027, CM120316, COSV99809649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 49/564 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- BOC | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs759609900; called by muse, mutect2
- CADPS2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761503610, COSV57358606; called by muse, mutect2, varscan2
- CDKN2A | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 73/658 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM035015, CM097978, COSV58696521; called by muse, mutect2
- CPN2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 28/292 reads (10%) | catalogued as rs758477993; called by muse, mutect2
- DACT1 | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs200318568; called by muse, mutect2, varscan2
- OSBP2 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs1042880246, COSV60241514; called by muse, mutect2, varscan2
- SLC12A6 | c.2042+2T>C p.X681_splice (on ENST00000354181 / NM_001365088.1; = p.X630_splice on NM_005135.2) | Splice Site (SNP) | VAF 25/217 reads (12%) | catalogued as COSV99271409; called by muse, mutect2, varscan2
- THEM6 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1554642439; called by muse, mutect2, varscan2
- ZFHX4 | c.5732C>T p.A1911V | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs373316359; called by muse, mutect2
- ARID1A | c.2988+2T>G p.X996_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- CACNA1C | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNOT1 | c.3542A>G p.K1181R | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- DDX17 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 58/561 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2
- FREM1 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTB4R | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2
- NPAS4 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- RNASEL | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCEL | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13C | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- WDTC1 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZBTB40 | c.1777A>C p.I593L | Missense Mutation (SNP) | VAF 53/402 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.2939C>T p.T980I | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CFAP46 | c.3060C>T p.F1020= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs1410921002; called by muse, varscan2
- GSX1 | c.147G>A p.A49= | Silent (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- HELZ2 | c.3501C>T p.F1167= (on ENST00000467148 / NM_001037335.2; = p.F598= on NM_033405.3) | Silent (SNP) | VAF 37/268 reads (14%) | catalogued as rs376041753; called by muse, mutect2, varscan2
- SLC39A12 | c.612G>A p.T204= | Silent (SNP) | VAF 50/338 reads (15%) | catalogued as rs773815080, COSV66195481; called by muse, mutect2, varscan2
- TNFAIP2 | c.180G>A p.A60= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV60693871; called by muse, mutect2
- TROAP | c.1551G>A p.P517= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as rs748007426; called by muse, mutect2
- AL353804.7 | chrX:73846084 C>T | 5'Flank (SNP) | VAF 18/80 reads (23%) | catalogued as rs764431964; called by muse, mutect2, varscan2
- AMT | c.1033+36C>T | Intron (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- BCAT1 | c.7-973G>A | Intron (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- BTBD8 | c.833+74T>G | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- INPP5K | c.-10G>T | 5'UTR (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- MAGEA3 | c.-91C>T | 5'UTR (SNP) | VAF 32/385 reads (8%) | called by muse, mutect2
- NLRP3 | c.-36G>A | 5'UTR (SNP) | VAF 27/334 reads (8%) | catalogued as rs755242195; called by muse, mutect2
- PKD1L2 | n.2718C>A | RNA (SNP) | VAF 16/190 reads (8%) | catalogued as rs542299761; called by muse, mutect2
